Gene-level copy-number profile of tumor specimen TCGA-22-5473-01A from TCGA case TCGA-22-5473, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 78.9 years (28,826 days).
Specimen TCGA-22-5473-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.5fd59e1a-235f-49ff-a683-68ff1b83b5e3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5473-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/78828ccc-b533-4c5b-ad07-d2a9690775d9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 1,938; copy number 2: 25,077; copy number 3: 21,224; copy number 4: 6,196; copy number 5: 2,088; copy number 6: 1,543; copy number 7: 537; copy number 8: 189; copy number 9: 744; copy number 10: 153; copy number 11: 84; copy number 14: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5473-01A-01D-1631-01): tumor purity 0.58, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:116,043,407–116,044,045, 1 gene: EIF3KP3.
- chr4:164,188,311–164,197,711, 2 genes: AC105250.1, ANP32C.
- chr9:12,698,554–13,836,571, 13 genes (within-gene range 0–6): LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1.
- chr9:17,579,066–18,910,950, 7 genes (within-gene range 0–3): SH3GL2, PABPC1P11, ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1.
- chr9:21,967,752–22,214,672, 8 genes: CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,346 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:78,597,911–84,040,720, 47 genes, copy number 5: AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1.
- chr3:100,910,975–103,241,230, 36 genes, copy number 5: AC080014.1, RNU6-865P, ACTR3P3, IMPG2, SENP7, ZNF90P1, AC110994.1, AC110994.2, Y_RNA, FAM172BP, TRMT10C, PCNP, AC073861.1, AC084198.1, RNU6-1256P, Y_RNA, Y_RNA, ZBTB11, RNY1P12, ZBTB11-AS1, RPL24, AC084198.2, PDCL3P4, CEP97, NXPE3, AC020651.1, NFKBIZ, AC020651.2, LINC02085, Y_RNA, AC106712.1, ZPLD1, AC063938.1, RNU6-461P, RNU1-43P, NDUFA4P2.
- chr3:149,224,138–149,433,274, 9 genes, copy number 5: AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2.
- chr3:162,601,627–198,222,513, 644 genes, copy number 9–10 (within-gene range 4–10) (broad region; genes not listed).
- chr5:58,198–45,895,970, 709 genes, copy number 5–6 (broad region; genes not listed).
- chr7:70,972–35,038,271, 608 genes, copy number 5 (broad region; genes not listed).
- chr7:54,419,444–57,837,046, 154 genes, copy number 9 (broad region; genes not listed).
- chr7:74,453,790–110,534,757, 671 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:31,639,222–43,674,591, 232 genes, copy number 5–11 (broad region; genes not listed).
- chr8:52,110,839–75,034,558, 364 genes, copy number 5–6 (broad region; genes not listed).
- chr9:659,986–10,612,723, 131 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr9:10,948,372–12,710,285, 10 genes, copy number 6: AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1.
- chr9:13,927,971–17,503,923, 49 genes, copy number 5 (within-gene range 0–5): LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr10:44,712–38,360,098, 661 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:42,644,445–43,596,625, 28 genes, copy number 8 (within-gene range 1–8): LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2, ZNF239, AL450326.3.
- chr11:130,314,993–130,717,352, 7 genes, copy number 10 (within-gene range 2–10): ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873.
- chr12:66,767–34,249,958, 850 genes, copy number 6–8 (broad region; genes not listed).
- chr12:38,201,566–47,236,662, 124 genes, copy number 5 (broad region; genes not listed).
- chr12:70,366,290–71,441,898, 12 genes, copy number 6 (within-gene range 4–6): KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8.

Autosomal genes at a single copy (total copy number 1): 334. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
